Gene-level copy-number profile of tumor specimen TCGA-ER-A19L-06A from TCGA case TCGA-ER-A19L, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.6 years (16,652 days).
Specimen TCGA-ER-A19L-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8805a867-1686-420b-a611-826b8304151a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c395978-59de-47e6-9643-d023be8328a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 15,550; copy number 2: 37,614; copy number 3: 3,357; copy number 4: 2,846; copy number 5: 246; copy number 6: 40; copy number 7: 2; copy number 8: 7; copy number 9: 10; copy number 14: 53; copy number 15: 64; copy number 18: 2; copy number 22: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19L-06A-12D-A191-01): tumor purity 0.87, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:176,844,493–177,301,253, 3 genes (within-gene range 0–1): AC097518.2, AC092673.1, LINC02509.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 397 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,414,931–121,580,524, 64 genes, copy number 15 (broad region; genes not listed).
- chr1:148,795,797–149,556,361, 18 genes, copy number 5–7: AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr4:181,590,255–182,145,249, 6 genes, copy number 5: AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr4:182,144,852–182,190,382, 2 genes, copy number 5: AC108142.1, MIR1305.
- chr8:83,912,713–84,921,844, 6 genes, copy number 6 (within-gene range 4–6): AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2.
- chr8:115,408,496–115,809,673, 1 gene, copy number 5 (within-gene range 1–5): TRPS1.
- chr8:120,761,253–121,994,185, 8 genes, copy number 5 (within-gene range 4–5): AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855.
- chr11:72,080,331–73,369,388, 53 genes, copy number 14 (within-gene range 1–14): AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17.
- chr11:97,222,644–98,945,079, 8 genes, copy number 18–22 (within-gene range 1–22): LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1.
- chr11:99,120,176–99,120,490, 1 gene, copy number 22: RN7SKP53.
- chr12:66,767–2,697,950, 52 genes, copy number 5 (within-gene range 4–5): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1.
- chr20:15,892,355–17,484,578, 21 genes, copy number 5–8 (within-gene range 3–8): AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1.
- chr20:18,782,424–19,722,926, 10 genes, copy number 9 (within-gene range 1–9): EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1.
- chr20:48,007,875–51,562,831, 83 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:52,890,162–52,890,386, 1 gene, copy number 5: RPL36P1.
- chr20:63,337,339–64,313,132, 63 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
